Somatic mutation profile of tumor specimen TCGA-B7-A5TK-01A (aliquot TCGA-B7-A5TK-01A-12D-A31L-08) from TCGA case TCGA-B7-A5TK, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 51.3 years (18,750 days).
Specimen TCGA-B7-A5TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a46e18c-f9a4-4ec2-9ea7-4d5582fbd006.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B7-A5TK-10A (Blood Derived Normal), aliquot TCGA-B7-A5TK-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5246529d-2a97-4737-95c4-7d96a447321a

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 30, Silent 19, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APBB1IP | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); catalogued as COSV100774384; called by muse, mutect2, varscan2
- API5 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs199828377, COSV101124543; called by muse, varscan2
- BFSP1 | c.1223G>T p.S408I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV100925374; called by muse, mutect2
- CAMKMT | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV101034836; called by muse, mutect2, varscan2
- CSMD3 | c.6208G>T p.V2070F (on ENST00000297405 / NM_001363185.1; = p.V1966F on NM_052900.3) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99835849; called by muse, mutect2
- DAPK3 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100009702; called by muse, mutect2
- DLG2 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs762858195, COSV54687670; called by muse, mutect2, varscan2
- DNAI1 | c.1715T>C p.I572T | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99646860; called by muse, mutect2, varscan2
- DOT1L | c.3167C>T p.A1056V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV101288679, COSV67107990; called by muse, mutect2, varscan2
- FLNA | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as rs782450368, COSV61037753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRC6A | c.1895T>C p.V632A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs144806246; called by muse, mutect2, varscan2
- HCN1 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 9/125 reads (7%) | catalogued as rs534013981, COSV57513022, COSV57529311; called by muse, mutect2
- HIVEP3 | c.5311A>G p.K1771E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99912803; called by muse, mutect2, varscan2
- MAP3K4 | c.3508A>T p.T1170S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV100815405; called by muse, varscan2
- MCF2L | c.1310G>A p.R437Q (on ENST00000375608; = p.R405Q on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs367959410; called by muse, mutect2, varscan2
- METTL5 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99641723; called by muse, mutect2
- MROH5 | c.2704C>T p.P902S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV101436006; called by muse, varscan2
- MUC6 | c.5026A>T p.S1676C | Missense Mutation (SNP) | VAF 37/1181 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV101424623; called by muse, mutect2
- NCAM1 | c.2050G>A p.V684M (on ENST00000316851 / NM_181351.5; = p.V674M on NM_000615.7) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs899421554, COSV100377836; called by muse, mutect2
- NRXN1 | c.3490G>A p.V1164I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as rs201881725, COSV58458700; called by muse, mutect2, varscan2
- SCN4B | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs766890974, COSV100228676; called by muse, mutect2, varscan2
- SCNN1D | c.1240C>A p.L414M (on ENST00000338555; = p.L578M on NM_001130413.4) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100329957; called by muse, mutect2, varscan2
- SIPA1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs749443708, COSV100856432; called by muse, varscan2
- SLC5A9 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764835227, COSV99361707; called by muse, mutect2, varscan2
- TCHH | c.5297G>A p.R1766H | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV64276176; called by muse, mutect2, varscan2
- TMEM26 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as COSV67492748; called by muse, mutect2, varscan2
- TNS4 | c.1139G>T p.C380F | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99563867; called by muse, mutect2, varscan2
- TRPC6 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100723644, COSV60258048; called by muse, mutect2, varscan2
- WDR88 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as rs746514517, COSV63450709; called by muse, mutect2, varscan2
- XKRX | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60708947; called by muse, mutect2, varscan2
- YLPM1 | c.5233C>G p.Q1745E | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV99459826; called by muse, mutect2, varscan2
- ADM2 | c.311_316del p.Q104_L105del | In Frame Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- AFF4 | c.333_358del p.G112Sfs*12 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- ALAS1 | c.1147del p.T383Lfs*78 | Frame Shift Del (DEL) | VAF 13/120 reads (11%) | called by mutect2, pindel, varscan2
- ARID1A | c.2181_2185del p.P728Qfs*87 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- AIM2 | c.174G>A p.A58= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs760542046, COSV100931082; called by muse, mutect2, varscan2
- BAZ1B | c.1995T>C p.D665= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs782649143, COSV100289821; called by muse, mutect2, varscan2
- CDK13 | c.1116C>A p.R372= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99475604; called by muse, varscan2
- CSDE1 | c.1086C>T p.F362= (on ENST00000358528 / NM_001007553.3; = p.F331= on NM_007158.6) | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99795146; called by muse, mutect2, varscan2
- DCAF12L2 | c.252C>A p.P84= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100758636, COSV63581468; called by mutect2, varscan2
- DHRS2 | c.609G>T p.L203= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99159179; called by muse, mutect2, varscan2
- EBF3 | c.1065C>T p.Y355= (on ENST00000355311 / NM_001375392.1; = p.Y346= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as rs200561162, COSV100799250; called by muse, mutect2
- EXOC6B | c.363A>G p.R121= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99724515; called by muse, mutect2
- H2AC20 | c.303C>T p.V101= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as rs782127378, COSV58612668; called by muse, mutect2
- HDAC1 | c.1191C>T p.D397= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as rs552958105, COSV61482157; called by muse, mutect2, varscan2
- KIF22 | c.1653G>A p.L551= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99361183; called by muse, mutect2, varscan2
- LRRC8E | c.1944C>T p.H648= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs745395721, COSV60719333; called by muse, mutect2, varscan2
- MUC2 | c.3786G>A p.P1262= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs373829324; called by muse, mutect2
- MYRF | c.1176C>T p.D392= (on ENST00000278836 / NM_001127392.3; = p.D383= on NM_013279.4) | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs771182649, COSV53896051; called by muse, mutect2, varscan2
- PKHD1 | c.11853C>A p.S3951= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV100944337; called by muse, mutect2, varscan2
- RBM39 | c.1110G>A p.Q370= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99488605; called by muse, mutect2
- TBX5 | c.39G>A p.T13= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV59858611; called by muse, mutect2, varscan2
- UHRF1 | c.279C>T p.T93= (on ENST00000612630 / NM_001290050.1; = p.T106= on NM_013282.4) | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs760355998, COSV53576784; called by muse, mutect2, varscan2
- ZNF536 | c.2226C>T p.R742= | Silent (SNP) | VAF 19/197 reads (10%) | catalogued as rs371053007, COSV62834704; called by muse, mutect2, varscan2
